CCDI case PBCDHU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/38da5a43-bdc2-43b0-8349-563e13684587

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Tumor cells, uncertain whether benign or malignant: ICD-O-3 morphology code: 8001/1; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 15.6 years (5,706 days).

Biospecimens (3 samples)
- Sample 0DP6HM: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DP6I6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DP6IC: Tissue type: Tumor; Specimen type: Solid Tissue.
